Somatic mutation profile of cancer-model specimen HCM-SANG-0267-D12-85A (3D Organoid; aliquot HCM-SANG-0267-D12-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0267-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0267-D12-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6f11815-16f5-4205-8cd3-8434cdfcc74a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0267-D12-10A (Blood Derived Normal), aliquot HCM-SANG-0267-D12-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dcc6d2e-fa70-4b0b-92c3-7bb99448af5a

The open-access MAF lists 203 somatic variants for this specimen: 146 protein-altering or splice-affecting, 48 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 48, Nonsense Mutation 9, Splice Region 5, Intron 4, Frame Shift Del 3, Splice Site 2, 5'Flank 2, 5'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 49/103 reads (48%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 438/671 reads (65%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 119/233 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG5 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs148186696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSBG1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 217/374 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs774668709, COSV51906562; called by muse, mutect2, varscan2
- ADAMTS7 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 184/409 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs758723833; called by muse, mutect2, varscan2
- ADGRL1 | c.2387A>G p.N796S (on ENST00000340736 / NM_001008701.3; = p.N791S on NM_014921.5) | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs757599356; called by muse, mutect2
- ADRA1D | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 148/282 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1015715330; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2972C>T p.T991M | Missense Mutation (SNP) | VAF 111/249 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs377446677; called by muse, mutect2, varscan2
- APEX1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 140/290 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752473392, COSV99032172; called by muse, mutect2, varscan2
- ASIC4 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 237/486 reads (49%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.776); catalogued as rs770046746; called by muse, mutect2, varscan2
- ASPM | c.5186G>A p.R1729Q | Missense Mutation (SNP) | VAF 149/717 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.227); catalogued as rs768999000, COSV54128816, COSV54128933; called by muse, mutect2, varscan2
- B3GALT1 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 187/356 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs150305076; called by muse, mutect2, varscan2
- BPIFC | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 136/312 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs78469100, COSV55910676; called by muse, mutect2, varscan2
- CAPNS2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs558136505, COSV50896584; called by muse, mutect2
- CD1E | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 171/755 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100937010, COSV63770217; called by muse, mutect2, varscan2
- CELSR3 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 249/549 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1372477014, COSV50902205, COSV99375140; called by muse, mutect2, varscan2
- CFAP99 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 137/310 reads (44%) | catalogued as rs537841039; called by muse, mutect2, varscan2
- CHST9 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV52434844, COSV99410344; called by muse, mutect2, varscan2
- CLIP1 | c.3822G>C p.Q1274H (on ENST00000620786 / NM_001247997.1; = p.Q1263H on NM_002956.2) | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV56797670; called by muse, mutect2
- COA5 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs376113873; called by muse, mutect2, varscan2
- COL15A1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 66/825 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as rs374984385; called by muse, mutect2
- DNAJC6 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 133/288 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs549580287; called by muse, mutect2, varscan2
- DRC1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1311428069; called by muse, mutect2, varscan2
- EEA1 | c.1079T>A p.L360Q | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1414802587; called by muse, mutect2, varscan2
- EFNA2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 295/669 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs763961946; called by muse, mutect2, varscan2
- ERN1 | c.2605G>A p.V869M | Missense Mutation (SNP) | VAF 149/335 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778413463; called by muse, mutect2, varscan2
- F11R | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 23/521 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV57041124; called by muse, mutect2
- FAM53B | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 131/270 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1410825842; called by muse, mutect2, varscan2
- GABRA5 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1274121828, COSV104409320; called by muse, mutect2, varscan2
- GNA13 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 33/333 reads (10%) | catalogued as COSV71474564; called by muse, mutect2, varscan2
- GRAP2 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 230/457 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777566631, COSV59995855; called by muse, varscan2
- GRM6 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 102/229 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs774644036, COSV51436399; called by muse, mutect2, varscan2
- H3-5 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 269/543 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV100461701; called by muse, mutect2
- HACD3 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.787); catalogued as COSV99971273; called by muse, mutect2, varscan2
- HECW1 | c.4690A>G p.K1564E | Missense Mutation (SNP) | VAF 123/377 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as rs1279263202; called by muse, mutect2, varscan2
- HERC2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 205/440 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as rs772532798; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPB2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 272/516 reads (53%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.541); catalogued as rs1555165860, COSV57051679; called by muse, mutect2, varscan2
- IGF2BP1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 177/385 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as COSV51731837; called by muse, mutect2, varscan2
- KATNAL1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs764643579, COSV66064741; called by muse, mutect2
- KCNG2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 224/586 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs544952689; called by muse, mutect2, varscan2
- KIF13B | c.3275G>T p.R1092L | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72954492; called by muse, mutect2, varscan2
- KRT82 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 167/347 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs113026141; called by muse, mutect2, varscan2
- MAGI1 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as rs1188679788; called by muse, mutect2, varscan2
- MAP2 | c.5164C>T p.R1722C | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749308409, COSV52281337; called by muse, mutect2
- MCMBP | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 139/301 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760211029; called by muse, mutect2, varscan2
- METAP1D | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 204/446 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs2120353; called by muse, mutect2, varscan2
- MOK | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs747272869, COSV99513778; called by muse, mutect2, varscan2
- MYH6 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 137/295 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs576497958; called by muse, mutect2, varscan2
- NAALADL2 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs1215194834; called by muse, mutect2, varscan2
- NETO1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 159/313 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1204319408; called by muse, mutect2, varscan2
- NMBR | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 112/496 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs758523214; called by muse, mutect2, varscan2
- NRN1L | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 277/560 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs769584336; called by muse, mutect2, varscan2
- NSUN5 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 496/732 reads (68%) | catalogued as rs374889055; called by muse, mutect2, varscan2
- OLIG2 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 53/589 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs768519339, COSV60972172; called by muse, mutect2
- OR2W3 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 469/627 reads (75%) | SIFT tolerated (0.52); PolyPhen benign (0.182); catalogued as rs369250388, COSV64456271; called by muse, mutect2, varscan2
- P2RX7 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201451288; called by muse, mutect2, varscan2
- PCDHGA8 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 140/286 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV53986400; called by muse, mutect2, varscan2
- PDE7B | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 153/372 reads (41%) | catalogued as rs193920799, COSV57492185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEBP1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 122/259 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs745741685; called by muse, mutect2, varscan2
- PGS1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 142/288 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749520109; called by muse, mutect2, varscan2
- RAD51AP1 | c.1039C>G p.P347A (on ENST00000228843 / NM_001130862.2; = p.P330A on NM_006479.5) | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57409662; called by muse, mutect2
- ROR1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 152/296 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as rs371110337; called by muse, mutect2, varscan2
- RYR3 | c.6670C>T p.R2224C | Missense Mutation (SNP) | VAF 17/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1188037949, COSV63109442; ClinVar: uncertain significance; called by muse, mutect2
- SHANK1 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 320/584 reads (55%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV53259143; called by muse, mutect2, varscan2
- SIPA1L2 | c.4195G>A p.G1399S | Missense Mutation (SNP) | VAF 499/694 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs200136990; called by muse, mutect2, varscan2
- SLC26A9 | c.951C>T p.R317= | Splice Region (SNP) | VAF 96/679 reads (14%) | catalogued as rs760498151, COSV61602677; called by muse, mutect2, varscan2
- SLC38A2 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 139/296 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1464532773, COSV56744065; called by muse, mutect2, varscan2
- SLC38A6 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555358125; called by muse, mutect2, varscan2
- SLC7A2 | c.1621G>A p.V541I (on ENST00000494857 / NM_001370338.1; = p.V580I on NM_003046.6) | Missense Mutation (SNP) | VAF 152/339 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs368801565; called by muse, mutect2
- SMTNL2 | c.1373G>A p.R458H (on ENST00000389313 / NM_001114974.2; = p.R314H on NM_198501.3) | Missense Mutation (SNP) | VAF 98/283 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1300405248; called by muse, mutect2, varscan2
- STAT3 | c.1599G>A p.L533= | Splice Region (SNP) | VAF 135/261 reads (52%) | catalogued as COSV99233056; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 116/240 reads (48%) | catalogued as rs745872748; called by mutect2, varscan2
- TFAP2E | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 48/469 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759784927, COSV64696784; called by muse, mutect2, varscan2
- TGIF1 | c.183G>A p.Q61= (on ENST00000330513 / NM_001374396.1; = p.Q81= on NM_003244.4) | Splice Region (SNP) | VAF 206/395 reads (52%) | catalogued as COSV57909842; called by muse, mutect2, varscan2
- TMEM132E | c.2480G>A p.R827Q (on ENST00000321639; = p.R917Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 218/619 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs757230221; called by muse, mutect2, varscan2
- TTN | c.28193C>T p.A9398V (on ENST00000591111; = p.A8471V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/215 reads (39%) | PolyPhen benign (0.425); catalogued as rs533172128, COSV60211703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VANGL1 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs371428273; called by muse, mutect2, varscan2
- WDR90 | c.2060C>T p.T687M | Missense Mutation (SNP) | VAF 263/531 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs756640844; called by muse, mutect2, varscan2
- WFS1 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 300/585 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as rs143055296, CM1515115, COSV99901167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WRAP53 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 263/524 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs35123152; called by muse, mutect2, varscan2
- ZFHX4 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50496590, COSV51487275; called by muse, mutect2, varscan2
- ZIM2 | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 37/379 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55628541; called by muse, mutect2
- ZNF467 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 271/836 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1305334072; called by muse, mutect2, varscan2
- ZNF92 | c.594G>C p.E198D (on ENST00000328747 / NM_152626.4; = p.E129D on NM_007139.4) | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV60875717; called by muse, mutect2, varscan2
- ABCC4 | c.983G>C p.S328T | Missense Mutation (SNP) | VAF 136/418 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADAMTS13 | c.849G>T p.W283C | Missense Mutation (SNP) | VAF 23/773 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); called by muse, mutect2
- ALOX5 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 184/398 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- APC | c.4473del p.F1491Lfs*16 | Frame Shift Del (DEL) | VAF 140/350 reads (40%) | called by mutect2, pindel, varscan2
- ATP1B1 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 131/599 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCL9L | c.2900C>A p.A967D | Missense Mutation (SNP) | VAF 223/528 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- C8orf82 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 255/497 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- C8orf82 | c.612G>C p.M204I | Missense Mutation (SNP) | VAF 254/501 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C9 | c.1355T>A p.V452E | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CD2 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CDX2 | c.630C>A p.Y210* | Nonsense Mutation (SNP) | VAF 140/515 reads (27%) | called by muse, mutect2, varscan2
- CFAP43 | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CHST12 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 190/661 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COCH | c.876T>A p.D292E (on ENST00000216361 / NM_001347720.1; = p.D227E on NM_004086.3) | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- COL22A1 | c.1184A>T p.N395I | Missense Mutation (SNP) | VAF 133/336 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DMD | c.4030C>A p.L1344I | Missense Mutation (SNP) | VAF 183/186 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- DMTF1 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 168/510 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DNAH14 | c.1303C>T p.Q435* (on ENST00000445597; = p.Q416* on NM_001145154.3) | Nonsense Mutation (SNP) | VAF 87/558 reads (16%) | called by muse, mutect2, varscan2
- DOCK3 | c.4799A>G p.H1600R | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- DYNC1H1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 115/273 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DYNC1I2 | c.336-1G>C p.X112_splice | Splice Site (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- EDEM2 | c.1236A>T p.T412= | Splice Region (SNP) | VAF 60/283 reads (21%) | called by muse, mutect2, varscan2
- F11R | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 23/529 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- F11R | c.596T>A p.F199Y | Missense Mutation (SNP) | VAF 23/513 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); called by muse, mutect2
- FAM170A | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 11/355 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2
- FBN3 | c.5489G>A p.C1830Y | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FKBP1B | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FRMD4B | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GPCPD1 | c.690C>G p.I230M | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HMCN1 | c.5263G>T p.D1755Y | Missense Mutation (SNP) | VAF 104/408 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- IARS1 | c.2566G>A p.D856N | Missense Mutation (SNP) | VAF 157/268 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KIF4B | c.3045C>G p.D1015E | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); called by muse, mutect2
- LHX1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 209/457 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LRRC37B | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 146/290 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MAP3K5 | c.2168A>C p.H723P | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MED12L | c.5558C>G p.A1853G | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- MMP2 | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 45/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- MSH4 | c.2023T>C p.F675L | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NRXN1 | c.212A>C p.D71A | Missense Mutation (SNP) | VAF 226/529 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- OR4K14 | c.79T>A p.F27I | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- OR6Q1 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 216/455 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PAPPA2 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 585/805 reads (73%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCSK5 | c.3472G>T p.G1158W | Missense Mutation (SNP) | VAF 28/598 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRR14L | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PRR30 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 222/486 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PYM1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 208/483 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RIMS2 | c.2723A>C p.D908A (on ENST00000666250 / NM_001348490.2; = p.D716A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/183 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SLC37A4 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX8 | c.918T>C p.G306= | Splice Region (SNP) | VAF 60/513 reads (12%) | called by muse, mutect2, varscan2
- SRRD | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 194/355 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- THEGL | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 202/451 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TMEM67 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM77 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 188/384 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TWIST1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 137/410 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- UBR1 | c.1678_1679del p.L560Tfs*5 | Frame Shift Del (DEL) | VAF 86/241 reads (36%) | called by mutect2, pindel, varscan2
- UNC13A | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 196/378 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WWC1 | c.2001-1G>C p.X667_splice | Splice Site (SNP) | VAF 120/241 reads (50%) | called by muse, mutect2, varscan2
- ZBTB4 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 125/591 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP57 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- ZNF225 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF638 | c.3596C>G p.A1199G | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.063); called by muse, mutect2
- AAK1 | c.2055C>T p.N685= | Silent (SNP) | VAF 140/285 reads (49%) | catalogued as rs371548831; called by muse, mutect2, varscan2
- AOAH | c.1680G>A p.P560= | Silent (SNP) | VAF 115/617 reads (19%) | called by muse, mutect2, varscan2
- ARAP2 | c.1017C>G p.L339= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as COSV58293654; called by muse, mutect2, varscan2
- ATP2B2 | c.1023C>T p.D341= (on ENST00000352432; = p.D307= on NM_001683.5) | Silent (SNP) | VAF 107/317 reads (34%) | catalogued as rs369726075, COSV59504958; called by muse, mutect2, varscan2
- CACNA1B | c.5145G>A p.T1715= | Silent (SNP) | VAF 144/454 reads (32%) | catalogued as rs1230477201, COSV53112391; called by muse, mutect2, varscan2
- CD93 | c.1047C>T p.C349= | Silent (SNP) | VAF 173/723 reads (24%) | called by muse, mutect2, varscan2
- CTNNA3 | c.114A>G p.V38= | Silent (SNP) | VAF 87/175 reads (50%) | called by muse, mutect2, varscan2
- DDR2 | c.471G>T p.P157= | Silent (SNP) | VAF 460/643 reads (72%) | catalogued as rs374094270; called by muse, mutect2, varscan2
- DLGAP1 | c.513C>T p.D171= | Silent (SNP) | VAF 272/579 reads (47%) | catalogued as COSV59782356; called by muse, mutect2, varscan2
- DOCK3 | c.4185G>A p.P1395= | Silent (SNP) | VAF 126/383 reads (33%) | catalogued as rs367930026; called by muse, mutect2, varscan2
- ECE1 | c.2031G>A p.A677= | Silent (SNP) | VAF 135/308 reads (44%) | catalogued as rs764345139; called by muse, mutect2, varscan2
- FRAS1 | c.2856C>T p.T952= | Silent (SNP) | VAF 78/218 reads (36%) | called by muse, mutect2, varscan2
- FZD8 | c.1536G>A p.S512= | Silent (SNP) | VAF 220/420 reads (52%) | catalogued as rs1290191206, COSV65967526; called by muse, mutect2, varscan2
- GRAMD4 | c.1038C>T p.F346= | Silent (SNP) | VAF 190/373 reads (51%) | catalogued as rs1054130178; called by muse, mutect2, varscan2
- GRK7 | c.789T>C p.H263= | Silent (SNP) | VAF 55/475 reads (12%) | catalogued as rs1170317891; called by muse, mutect2, varscan2
- HPS6 | c.354C>T p.T118= | Silent (SNP) | VAF 380/819 reads (46%) | catalogued as rs1288379163; called by muse, mutect2, varscan2
- IGF1R | c.3672C>T p.F1224= | Silent (SNP) | VAF 174/384 reads (45%) | catalogued as rs764671728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITIH5 | c.912T>G p.A304= | Silent (SNP) | VAF 109/249 reads (44%) | catalogued as COSV53663070; called by muse, mutect2, varscan2
- KCNQ2 | c.2331C>T p.P777= (on ENST00000359125 / NM_172107.4; = p.P749= on NM_004518.6) | Silent (SNP) | VAF 655/949 reads (69%) | catalogued as rs903555499, COSV60545621; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEGF11 | c.3114G>A p.P1038= | Silent (SNP) | VAF 127/281 reads (45%) | catalogued as rs377174263; called by muse, mutect2, varscan2
- NKX1-1 | c.648C>T p.G216= | Silent (SNP) | VAF 15/539 reads (3%) | called by muse, mutect2
- NTN5 | c.558C>T p.C186= | Silent (SNP) | VAF 319/635 reads (50%) | catalogued as rs1241022978; called by muse, mutect2, varscan2
- OR2T1 | c.348C>T p.L116= | Silent (SNP) | VAF 215/1149 reads (19%) | catalogued as COSV63542385; called by muse, mutect2, varscan2
- OR52N2 | c.123C>T p.V41= | Silent (SNP) | VAF 196/378 reads (52%) | catalogued as rs112125234, COSV100396225; called by muse, mutect2, varscan2
- PCDHA10 | c.1440C>T p.D480= | Silent (SNP) | VAF 302/628 reads (48%) | catalogued as COSV56500259; called by muse, mutect2, varscan2
- PCDHA9 | c.1368G>A p.A456= | Silent (SNP) | VAF 18/663 reads (3%) | catalogued as rs782077016, COSV65324753, COSV65332846; called by muse, mutect2
- PCDHB10 | c.1788G>A p.S596= | Silent (SNP) | VAF 153/581 reads (26%) | catalogued as rs1554284381; called by muse, mutect2, varscan2
- PCDHB5 | c.1662C>T p.N554= | Silent (SNP) | VAF 388/763 reads (51%) | catalogued as rs368703808; called by muse, mutect2, varscan2
- PEX6 | c.2181C>T p.H727= | Silent (SNP) | VAF 397/520 reads (76%) | called by muse, mutect2, varscan2
- PLCE1 | c.3837G>A p.S1279= | Silent (SNP) | VAF 100/213 reads (47%) | catalogued as rs754326671; called by muse, mutect2, varscan2
- PRDX2 | c.372T>C p.I124= | Silent (SNP) | VAF 119/258 reads (46%) | called by muse, mutect2, varscan2
- PRRT3 | c.1686G>C p.A562= | Silent (SNP) | VAF 268/518 reads (52%) | catalogued as rs758306980; called by muse, mutect2, varscan2
- RASGRF1 | c.264G>A p.P88= | Silent (SNP) | VAF 152/357 reads (43%) | catalogued as rs1335518170, COSV69181523; called by muse, mutect2, varscan2
- RGMA | c.267G>A p.T89= | Silent (SNP) | VAF 252/559 reads (45%) | catalogued as rs557195147; called by muse, mutect2, varscan2
- ROR1 | c.2490G>A p.A830= | Silent (SNP) | VAF 202/413 reads (49%) | catalogued as rs146764088; called by muse, mutect2, varscan2
- SHISA7 | c.1572G>A p.L524= | Silent (SNP) | VAF 189/422 reads (45%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4434C>T p.G1478= | Silent (SNP) | VAF 335/340 reads (99%) | catalogued as rs1010949429; called by muse, mutect2, varscan2
- SIK2 | c.2250G>A p.Q750= | Silent (SNP) | VAF 251/489 reads (51%) | called by muse, mutect2, varscan2
- SLC16A5 | c.525C>T p.F175= | Silent (SNP) | VAF 211/496 reads (43%) | catalogued as rs761950014; called by muse, mutect2, varscan2
- STARD10 | c.759G>A p.S253= | Silent (SNP) | VAF 259/526 reads (49%) | catalogued as rs895513563; called by muse, mutect2, varscan2
- STK11IP | c.360C>G p.L120= | Silent (SNP) | VAF 20/334 reads (6%) | catalogued as rs773437658; called by muse, mutect2
- SYNPO | c.2226T>G p.S742= (on ENST00000394243 / NM_001166208.2; = p.S498= on NM_007286.6) | Silent (SNP) | VAF 303/651 reads (47%) | called by muse, mutect2, varscan2
- TLL2 | c.498C>T p.Y166= | Silent (SNP) | VAF 122/238 reads (51%) | catalogued as rs763235245, COSV63573574; called by muse, mutect2, varscan2
- TRPV2 | c.1647C>T p.F549= | Silent (SNP) | VAF 139/321 reads (43%) | catalogued as rs751435857; called by muse, mutect2, varscan2
- TTN | c.26742C>T p.T8914= (on ENST00000591111; = p.T7987= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/354 reads (10%) | catalogued as rs752794790; called by muse, mutect2, varscan2
- UROC1 | c.747C>T p.L249= | Silent (SNP) | VAF 287/529 reads (54%) | catalogued as rs766972220, COSV52035114; called by muse, mutect2, varscan2
- USP17L1 | c.276C>T p.N92= | Silent (SNP) | VAF 75/300 reads (25%) | catalogued as rs750022874; called by muse, varscan2
- ZNF208 | c.876A>G p.K292= | Silent (SNP) | VAF 44/269 reads (16%) | catalogued as COSV101237197; called by muse, mutect2, varscan2
- COL18A1-AS2 | chr21:45405405 G>A | 3'Flank (SNP) | VAF 22/573 reads (4%) | called by muse, mutect2
- DUSP22 | c.508+36C>T | Intron (SNP) | VAF 72/329 reads (22%) | catalogued as rs1194398045, COSV100739571; called by muse, mutect2, varscan2
- FRRS1L | c.-100G>T | 5'UTR (SNP) | VAF 149/547 reads (27%) | called by muse, mutect2, varscan2
- NACA | c.70+3964del | Intron (DEL) | VAF 159/418 reads (38%) | called by mutect2, pindel, varscan2
- NRG1 | chr8:31640176 G>A | 5'Flank (SNP) | VAF 186/354 reads (53%) | called by muse, varscan2
- PLA2G6 | c.210-2913C>T | Intron (SNP) | VAF 130/271 reads (48%) | catalogued as rs1006747639; called by muse, mutect2, varscan2
- PLCH2 | c.2959+420G>C | Intron (SNP) | VAF 244/554 reads (44%) | called by muse, mutect2, varscan2
- SERPINA9 | c.-14T>G | 5'UTR (SNP) | VAF 92/248 reads (37%) | called by muse, mutect2, varscan2
- TLE5 | chr19:3062850 G>T | 5'Flank (SNP) | VAF 219/447 reads (49%) | called by muse, mutect2, varscan2
